Somatic mutation profile of tumor specimen ALCH-B35L-TTP1-A (aliquot ALCH-B35L-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B35L, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.3 years (26,421 days).
Specimen ALCH-B35L-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56a07c14-e8e2-4658-807b-71a391c52b6d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B35L-NB1-A (Blood Derived Normal), aliquot ALCH-B35L-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aaba35b7-dbe0-4f96-b861-cdea6148a81c

The open-access MAF lists 65 somatic variants for this specimen: 46 protein-altering or splice-affecting, 11 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 11, Intron 5, RNA 3, Frame Shift Del 2, Splice Region 2, Nonsense Mutation 2, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 116/622 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 106/347 reads (31%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.835); catalogued as rs55832599, CM120851, COSV52678166, COSV52736883, COSV52827473; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTN2 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 24/481 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs773942709, COSV63975721; ClinVar: uncertain significance; called by muse, mutect2
- ATL1 | c.37G>A p.G13R | Missense Mutation (SNP) | VAF 20/359 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.346); catalogued as rs1566722874; called by muse, mutect2
- CRMP1 | c.1466T>C p.F489S | Missense Mutation (SNP) | VAF 32/348 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV61479164; called by muse, mutect2
- CTNNA2 | c.1948C>T p.R650C | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs776677678, COSV100560199, COSV58141407; called by muse, mutect2
- DISP2 | c.1607G>A p.R536H | Missense Mutation (SNP) | VAF 43/319 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.301); catalogued as rs779234646, COSV99140297; called by muse, mutect2, varscan2
- DPYSL5 | c.1609G>A p.G537S | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV99982815; called by mutect2, varscan2
- DSG4 | c.2774T>G p.F925C | Missense Mutation (SNP) | VAF 22/228 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.682); catalogued as COSV100355982; called by muse, mutect2
- EIF2AK3 | c.827C>G p.A276G | Missense Mutation (SNP) | VAF 22/298 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.053); catalogued as COSV57545781; called by muse, mutect2
- FAT3 | c.2302G>A p.G768R | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1342926494; called by muse, mutect2, varscan2
- GPATCH2 | c.1462C>T p.R488* | Nonsense Mutation (SNP) | VAF 30/559 reads (5%) | catalogued as rs753746760, COSV65133973; called by muse, mutect2
- ISG20 | c.31G>C p.D11H | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs911681615, COSV60144064; called by muse, mutect2, varscan2
- KRT6C | c.50G>C p.G17A | Missense Mutation (SNP) | VAF 55/580 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs755276539; called by muse, mutect2, varscan2
- MXRA5 | c.5803G>A p.G1935S | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1470253715, COSV54250099; called by muse, mutect2
- OR2C3 | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs201316551, COSV63574580; called by muse, mutect2, varscan2
- OTOF | c.1336G>A p.G446S | Missense Mutation (SNP) | VAF 32/308 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs146086924; called by muse, mutect2
- PDHA2 | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 22/397 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.058); catalogued as rs372154327; called by muse, mutect2
- PPP1R15B | c.2045C>T p.A682V | Missense Mutation (SNP) | VAF 21/324 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1363603991; called by muse, mutect2
- PRAMEF14 | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 74/532 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as rs1312967079; called by muse, mutect2, varscan2
- SEMA6B | c.370-2A>G p.X124_splice | Splice Site (SNP) | VAF 8/67 reads (12%) | catalogued as rs1555698169; called by mutect2, varscan2
- ZNF831 | c.1073C>T p.A358V | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs757084623; called by muse, mutect2, varscan2
- ACBD6 | c.68A>G p.D23G | Missense Mutation (SNP) | VAF 49/471 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ACO1 | c.198G>C p.W66C | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADAM32 | c.905G>C p.G302A | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- BDP1 | c.6564-1G>A p.X2188_splice | Splice Site (SNP) | VAF 16/222 reads (7%) | called by muse, mutect2
- EPHA1 | c.623T>G p.L208R | Missense Mutation (SNP) | VAF 37/212 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- GBP7 | c.389G>T p.S130I | Missense Mutation (SNP) | VAF 62/211 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HECTD1 | c.7748T>G p.L2583R | Missense Mutation (SNP) | VAF 17/254 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.386); called by muse, mutect2
- HOXC8 | c.98G>C p.G33A | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IL2RB | c.70G>T p.A24S | Missense Mutation (SNP) | VAF 23/413 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.242); called by muse, mutect2
- L1CAM | c.3128G>A p.C1043Y | Missense Mutation (SNP) | VAF 9/177 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- MXRA7 | c.531C>G p.F177L | Missense Mutation (SNP) | VAF 59/333 reads (18%) | PolyPhen benign (0.178); called by muse, mutect2, varscan2
- NAP1L2 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- NOSTRIN | c.1175A>C p.E392A (on ENST00000317647 / NM_001039724.4; = p.E314A on NM_052946.3) | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.399); called by muse, mutect2
- OR2AP1 | c.407G>A p.S136N | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR6P1 | c.622C>A p.L208I | Missense Mutation (SNP) | VAF 16/439 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.345); called by muse, mutect2
- RGS4 | c.341T>A p.I114N | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF187 | c.486A>G p.G162= | Splice Region (SNP) | VAF 5/44 reads (11%) | called by mutect2, varscan2
- SEC23B | c.845C>A p.P282Q | Missense Mutation (SNP) | VAF 55/431 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- SP6 | c.673C>T p.Q225* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2, varscan2
- TNNT2 | c.720G>A p.R240= (on ENST00000236918; = p.R237= on NM_000364.4) | Splice Region (SNP) | VAF 40/568 reads (7%) | called by muse, mutect2
- TUT4 | c.1401_1425del p.C467Wfs*15 | Frame Shift Del (DEL) | VAF 24/136 reads (18%) | called by mutect2, pindel
- ZIC4 | c.358A>C p.M120L | Missense Mutation (SNP) | VAF 16/229 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2
- ZNF264 | c.1133del p.K378Rfs*9 | Frame Shift Del (DEL) | VAF 22/195 reads (11%) | called by mutect2, pindel, varscan2
- ZNF282 | c.1659G>C p.K553N | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2
- ADAMTS12 | c.264G>A p.E88= | Silent (SNP) | VAF 24/592 reads (4%) | called by muse, mutect2
- AKAP9 | c.9588A>G p.K3196= (on ENST00000359028; = p.K3172= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/487 reads (6%) | called by muse, mutect2
- ATP6AP1 | c.1341C>T p.I447= | Silent (SNP) | VAF 132/349 reads (38%) | called by muse, mutect2, varscan2
- CLYBL | c.876G>A p.K292= | Silent (SNP) | VAF 13/115 reads (11%) | called by muse, mutect2, varscan2
- FAM47A | c.276C>T p.S92= | Silent (SNP) | VAF 10/208 reads (5%) | catalogued as rs1160295204, COSV60498356; called by muse, mutect2
- PCDH10 | c.2628C>T p.N876= | Silent (SNP) | VAF 14/160 reads (9%) | catalogued as rs759327780; called by muse, mutect2
- SENP2 | c.1020G>A p.R340= | Silent (SNP) | VAF 9/168 reads (5%) | called by muse, mutect2
- SMG8 | c.1530C>G p.A510= | Silent (SNP) | VAF 10/91 reads (11%) | called by muse, mutect2, varscan2
- WASHC3 | c.525T>C p.D175= | Silent (SNP) | VAF 37/143 reads (26%) | catalogued as rs369322586; called by muse, mutect2, varscan2
- ZNF536 | c.1488G>A p.P496= | Silent (SNP) | VAF 20/201 reads (10%) | catalogued as rs775857517, COSV100835495; called by muse, mutect2, varscan2
- ZNF711 | c.1584T>A p.T528= | Silent (SNP) | VAF 13/124 reads (10%) | called by muse, mutect2, varscan2
- C2CD5 | c.1902+56T>G | Intron (SNP) | VAF 7/50 reads (14%) | called by muse, mutect2, varscan2
- DCD | c.98-369C>T | Intron (SNP) | VAF 40/339 reads (12%) | called by muse, mutect2, varscan2
- LINC01098 | n.557G>A | RNA (SNP) | VAF 23/165 reads (14%) | catalogued as rs1313390103; called by muse, mutect2, varscan2
- MIR373 | n.23T>A | RNA (SNP) | VAF 20/189 reads (11%) | called by muse, mutect2, varscan2
- OSBPL6 | c.1621+99C>T | Intron (SNP) | VAF 9/75 reads (12%) | called by muse, mutect2, varscan2
- TGIF1 | c.183+114_183+155del | Intron (DEL) | VAF 18/124 reads (15%) | called by mutect2, pindel
- ZNF300P1 | n.1307G>T | RNA (SNP) | VAF 20/284 reads (7%) | called by muse, mutect2
- ZNF774 | c.104+609G>A | Intron (SNP) | VAF 46/429 reads (11%) | called by muse, mutect2, varscan2
